Somatic mutation profile of tumor specimen TCGA-BP-5180-01A (aliquot TCGA-BP-5180-01A-01D-1429-08) from TCGA case TCGA-BP-5180, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.1 years (19,413 days).
Specimen TCGA-BP-5180-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e237ab-2af9-4af5-9ef1-ff9bd1728c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5180-11A (Solid Tissue Normal), aliquot TCGA-BP-5180-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/583956ad-1fb6-4864-98e3-7bbd7c1b2ff9

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as rs869025619, CM951269, HD971372, COSV56543044, COSV56544065, COSV56563076; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV57860888; called by muse, mutect2
- ADGRA1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV66930229, COSV66931716; called by muse, mutect2, varscan2
- ANO8 | c.2177C>G p.S726W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50185215; called by muse, mutect2, varscan2
- AP3S2 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV60518863; called by muse, mutect2, varscan2
- ARID2 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.973); catalogued as COSV57608248; called by muse, varscan2
- CLIC6 | c.1856G>C p.S619T (on ENST00000360731 / NM_001317009.2; = p.S601T on NM_053277.3) | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs1179756031, COSV62448239; called by muse, mutect2, varscan2
- DOCK10 | c.2293T>G p.Y765D | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV51419729; called by muse, mutect2, varscan2
- EIF2S2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV66621832; called by muse, mutect2, varscan2
- IPO4 | c.767A>C p.N256T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV55780676; called by muse, mutect2, varscan2
- IPP | c.1079C>G p.T360S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV63432993; called by muse, varscan2
- IPP | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV63433011; called by muse, varscan2
- KIF2A | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 160/395 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV66945982; called by muse, mutect2, varscan2
- LIPI | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 132/333 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs762157175, COSV60713210; called by muse, mutect2, varscan2
- NALCN | c.4378C>G p.Q1460E | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1335710703, COSV51946337; called by muse, mutect2, varscan2
- NATD1 | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67541137; called by muse, mutect2, varscan2
- NCOA4 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782530033; called by muse, mutect2, varscan2
- NIPAL3 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50232950; called by muse, mutect2, varscan2
- OSBP2 | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60244858; called by muse, mutect2, varscan2
- PBRM1 | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV56285394; called by muse, mutect2, varscan2
- PCDHA12 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 137/374 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV56488117; called by muse, mutect2, varscan2
- PRKDC | c.4838A>G p.H1613R | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs767235558, COSV58056761; called by muse, mutect2, varscan2
- RASGRF1 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 131/395 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as COSV69180588; called by muse, mutect2, varscan2
- ROBO2 | c.3335C>G p.T1112S | Missense Mutation (SNP) | VAF 95/158 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.232); catalogued as COSV59920035; called by muse, mutect2, varscan2
- SCN1A | c.3665C>A p.T1222N (on ENST00000303395 / NM_001202435.3; = p.T1211N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV57675878; called by muse, mutect2, varscan2
- SULF1 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 45/153 reads (29%) | catalogued as COSV52683175; called by muse, mutect2, varscan2
- SYT3 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV58897553, COSV99075836; called by muse, mutect2
- TLE6 | c.565G>A p.E189K (on ENST00000246112 / NM_001143986.2; = p.E66K on NM_024760.3) | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as COSV55736433, COSV55737189; called by muse, mutect2, varscan2
- TRIM8 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV56661127; called by muse, mutect2
- ZNF77 | c.1395A>T p.E465D | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV58822215; called by muse, mutect2, varscan2
- CASP10 | c.123del p.L42Sfs*3 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | called by mutect2, pindel, varscan2
- DNAJC21 | c.269_270del p.R90Lfs*13 | Frame Shift Del (DEL) | VAF 49/188 reads (26%) | called by mutect2, pindel, varscan2
- IGLC2 | c.309_317delinsCAGAATGTT p.E104_S106delinsQNV | Missense Mutation (ONP) | VAF 25/178 reads (14%) | called by pindel, varscan2*
- RAB32 | c.627del p.K210Sfs*2 | Frame Shift Del (DEL) | VAF 81/170 reads (48%) | called by mutect2, pindel, varscan2
- VWA8 | c.721_731del p.L241Sfs*32 | Frame Shift Del (DEL) | VAF 47/157 reads (30%) | called by mutect2, pindel, varscan2
- CACNA1C | c.2925G>T p.L975= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as COSV59738723; called by muse, mutect2, varscan2
- HOXB3 | c.984G>A p.E328= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV57487547; called by muse, mutect2, varscan2
- PHRF1 | c.2811C>A p.P937= (on ENST00000264555 / NM_001286581.2; = p.P936= on NM_020901.4) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52758142; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4269G>A p.R1423= | Silent (SNP) | VAF 63/202 reads (31%) | catalogued as COSV54439276; called by muse, mutect2, varscan2
- VHL | c.216C>A p.S72= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs774557051, COSV56554272; ClinVar: likely benign; called by mutect2, varscan2
- WDCP | c.1341C>G p.T447= | Silent (SNP) | VAF 111/336 reads (33%) | catalogued as COSV54591376; called by muse, mutect2, varscan2
- EIF2S2 | c.-1C>A | 5'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100894931; called by muse, mutect2, varscan2
- KIAA1217 | c.-2C>T | 5'UTR (SNP) | VAF 20/74 reads (27%) | catalogued as rs764201102, COSV100907667; called by muse, mutect2
